Gene-level copy-number profile of tumor specimen C3L-04081-01 from CPTAC case C3L-04081, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.6 years (23,222 days).
Specimen C3L-04081-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bfe7dc57-9110-4957-a14f-f8efd5bc8631.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04081-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/b6f528a6-e828-471a-9c15-dab3ab709004

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 5; copy number 2: 7,226; copy number 3: 1,577; copy number 4: 45,421; copy number 5: 1,653; copy number 6: 2,932; copy number 10: 7; copy number 12: 1; copy number 66: 72; copy number 126: 1; copy number 182: 1; copy number 203: 8.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,033,646–12,043,670, 2 genes: AC107918.1, DEFB131C.
- chr8:12,333,644–12,333,693, 1 gene: RNA5SP254.
- chr10:87,994,618–87,994,695, 1 gene: AC063965.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 90 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:12,598,987–12,605,145, 1 gene, copy number 182: AC096559.1.
- chr2:15,801,747–16,149,394, 12 genes, copy number 10–203: AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1.
- chr2:16,853,820–16,855,284, 1 gene, copy number 126: AC008069.1.
- chr8:12,104,389–12,139,077, 4 genes, copy number 10–12: ZNF705D, AC130366.1, USP17L7, USP17L2.
- chr12:57,431,116–60,269,686, 72 genes, copy number 66 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
